CPTAC case C3N-02289 — Bronchus and lung — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a8f79795-cea1-46c0-bc33-a9544e92418b

Demographics
Sex at birth: male; Race: white; Year of birth: 1944; Vital status: Alive; Country of birth: Poland.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Upper lobe, lung; Age at diagnosis: 73.7 years (26,931 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,818 days (5.0 years); Progression or recurrence: no; Days to last follow up: 1,818 days (5.0 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 5 cm (a second GDC size field records 4 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 9; Margin status: Uninvolved.

Follow-up (6 entries)
- Days to follow up: 411 days (1.1 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 0.
- Days to follow up: 751 days (2.1 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 751 days (2.1 years); Disease response: Complete Response; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,091 days (3.0 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,407 days (3.9 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,818 days (5.0 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.

Other clinical attributes
- Weight: 75 kg; Height: 180 cm; BMI: 23.15.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-02289-06: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -4 days; Initial weight: 304 mg; Time between excision and freezing: 5 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02289-26: Section location: Right Upper Lobe; Percent tumor nuclei: 60; Percent necrosis: 2.
- Sample C3N-02289-09: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -4 days; Initial weight: 257 mg; Time between excision and freezing: 5 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-02289-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -4 days; Method of sample procurement: Blood Draw.
